Gene-level copy-number profile of tumor specimen TCGA-3U-A98D-01A from TCGA case TCGA-3U-A98D, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 80.8 years (29,500 days).
Specimen TCGA-3U-A98D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.930d698a-e1f2-43fd-b5b3-1db88cd1d102.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3U-A98D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6565a1ed-dfff-4cd7-9bfe-3f59dd82238c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 170; copy number 1: 21,820; copy number 2: 36,668; copy number 3: 1,152.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3U-A98D-01A-12D-A39Q-01): tumor purity 0.65, ploidy 1.64, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 159 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:96,583,209–96,696,167, 4 genes: RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270.
- chr3:121,356,991–121,357,940, 1 gene: AC079841.1.
- chr4:44,840,380–44,996,022, 3 genes: AC093755.1, PRDX4P1, AC108467.2.
- chr4:165,647,636–165,762,778, 3 genes (within-gene range 0–1): AC080079.2, AC080079.1, LINC01179.
- chr6:77,343,557–77,343,654, 1 gene: AL365222.1.
- chr9:19,705,338–24,088,051, 87 genes (broad region; genes not listed).
- chr10:98,383,565–98,453,805, 4 genes (within-gene range 0–1): PYROXD2, HPS1, MIR4685, AL139243.1.
- chr11:112,086,903–112,362,534, 14 genes (within-gene range 0–1): AP002884.2, IL18, AP002884.1, TEX12, BCO2, KCTD9P4, MRPS36P4, RPS12P21, PTS, RPS6P16, PLET1, AP002884.3, ST13P10, LINC02762.
- chr11:114,400,030–114,707,069, 11 genes (within-gene range 0–1): RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2.
- chr12:43,353,866–43,806,328, 9 genes (within-gene range 0–2): ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr12:44,008,620–44,010,143, 1 gene: ZNF75BP.
- chr12:45,475,520–46,270,017, 11 genes (within-gene range 0–1): AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3.
- chr12:47,075,707–47,346,297, 10 genes: AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19,410. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
